Surgical pathology report (de-identified scan), TCGA case TCGA-29-1690, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1690-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

Surg Path

TCGA-29-1690

GROSS EXAMINATION:

The specimen is received in seven separate containers.

A. "Omental cake", received fresh. There are two large masses of tumor which in aggregate weigh approximately 98.9 grams. The external surface of the tumor is firm and yellow and varies in consistency to smooth to rough. Throughout both tumor nodules the consistency and color is homogenous. Upon slicing there is a gritty and mucinous character to the masses.

Block Summary:

A1-representative section of larger tumor mass.
A2-representative section of smaller tumor mass.

B. "Cecum tumor nodules", fresh. Received fresh is a firm, nodular piece of fibroadipose tissue measuring 3 cm x 1 cm x 1 cm. Upon slicing this tissue a firm nodule of tumor entirely consistent with the tumor described in Block A is identified. Representative section is submitted in [REDACTED]

C. "Right ovary and tube". Received is a large structure which measures 66.9 grams and measures 6 x 3 x 3 cm. A large cyst is present on the structure which has been opened prior to receipt in the pathology laboratory. The large multiloculated mass is identified within the cyst cavity which varies in color from white to light yellow and is firm and fleshy throughout. The residual mucoid material from the cyst is present. No residual ovary or fallopian tube is identified within the large mass replacing the ovary.

Block Summary:

C1- representative sections through thin area of cyst wall.
C2- section through tumor and cyst wall.
C3- sections through thicker nodular portion of cyst wall.
C4- representative sections of tumor nodule.
C5- additional section of tumor nodule.

D. "Portion left ovary". Fresh. Received fresh are two large portions of yellowish mucinous tumor. The largest piece measures 5 x 4 x 4 cm, the smaller piece 7 x 3 x 2 cm. In aggregate the two specimen weigh approximately 69 grams. No identifiable ovary is present. Sectioning of both masses reveal a homogenous white to yellow gritty mass which exudes mucinous material upon cutting. Representative sections are submitted in [REDACTED]

E. "Uterus and left ovary", fresh. Received is a small portion of uterus measuring 3.5 x 4 x 2 cm and large cystic structure which replaces the left ovary which measures approximately 6 x 4 x 4 cm. The cervix is not identified. The uterus body is soft. The serosal surface of the uterus does not appear to contain any grossly identifiable nodules of the tumor. However, the serosal surface is very roughened and hemorrhagic. The large cystic mass replacing the left ovary is similar in appearance to the previously described nodules of tumor. The fallopian tube is difficult to identify secondary to the tumor burden.

Block Summary:

E1, E2- representative sections through uterus.
E3- multiple fallopian tube candidates.
E4- sections through tumor in area suspicious for residual ovary.
E5- additional section of tumor.

[REDACTED]

[page 2 of 2]
F. "Tumor on recto-sigmoid": Received are six fragments of hemorrhagic tumor which in aggregate measure approximately 4.5 x 4 x 2 cm. Representative sections are submitted in Blocks F1 and F2.

G. "Fibroid". The nodule weighs approximately 50 grams. Received is a large spheroid shape nodule which measures 4.5 x 4 x 2 cm. Palpation of this nodule reveals firm areas within the capsule of the nodule. There is cautery along the soft tissue margin of this nodule. Longitudinal sectioning of the nodule reveals a large mostly necrotic mass of white to yellow gritty tissue consistent with tumor described in previous areas. The central core of the nodule appears somewhat more viable than the remainder. Representative sections are submitted in Blocks G1 and G2.

CGA-29-1690

DIAGNOSIS:

OVARIES, BILATERAL (C,D,E): SEROUS ADENOCARCINOMA, FIGO GRADE 2, WITH MASSIVE PSAMMOMA COMPONENT (PSAMMOMOCARCINOMA), WITH MASSIVE METASTASES INVOLVING OMENTUM (A), CECUM (B), RIGHT FALLOPIAN TUBE (C), UTERUS (E), LEFT FALLOPIAN TUBE (E), RECTOSIGMOID REGION (F).

SUBMITTED AS UTERINE FIBROID (G): THE ENTIRE SPECIMEN CONSISTS OF METASTATIC SEROUS ADENOCARCINOMA.

ENDOMETRIUM (E): A SMALL FRAGMENT OF TUMOR IS PRESENT IN THE ATROPHIC ENDOMETRIUM. WHILE PART IS HIGHLY CILIATED, RAISING THE POSSIBILITY OF A SEPARATE PRIMARY, MUCH RESEMBLES THE TUMOR IN THE OVARY, FOR WHICH REASON THE ENDOMETRIAL TUMOR IS CONSIDERED TO BE IMPLANTATION.

ADDENDUM 1:

Immunostaining for carcinoembryonic antigen (CEA) is performed on sections from Block A1 ("omental cake") and D1 ("portion left ovary"). The immunostaining is done using DAKO rabbit anti-human CEA which is "the purified immunoglobulin fraction of rabbit antiserum". The section from Block A1 contains abundant adenocarcinoma with numerous psammoma bodies. There is very heterogeneous staining for CEA. There are foci of tumor in which all of the cells stain for CEA. Approximately 3/4 of these cells have moderately intense staining and 1/4 have markedly intense staining. These foci where all of the tumor cells stain comprise only a small portion of the tumor. The more common pattern of staining is where there are mixtures of positively staining and negatively staining cells adjacent to each other. In these areas, approximately 2/3 of the tumor cells stain positively. The staining intensity is evenly distributed between mildly intense and markedly intense in these areas. Though there is great variability in staining for CEA from one region of the tumor to the other, I estimate that approximately 50% of the tumor cells exhibit some degree of staining for CEA.

The histological sections of the left ovary also contain abundant tumor for evaluation. As with the metastasis to the omentum, the primary tumor exhibits marked heterogeneity in staining for CEA. There is one area of the tumor where there is necrotic debris and neutrophils between clusters of cancer cells. The debris and neutrophils stain positively which is a common cross-reaction with this antibody. There is more abundant staining of the tumor than was noted in the metastasis. There are many areas in which there are positively staining cells adjacent to negatively staining cells. There are also areas of the tumor in which many positively stained cells are adjacent to each other. The intensity of the tumor cell staining varies widely, as was noted in the metastasis. Approximately 40% of the positively staining cells exhibit markedly intense staining, 40% exhibit moderately intense staining and 20% exhibit mildly intense staining. Overall, I estimate that approximately 50% of the tumor cells exhibit expression of carcinoembryonic antigen.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file a0f09196-5ddc-41ed-8843-ba3e5f4d1fa9 (TCGA-29-1690.A44F0507-FC95-410A-A6B2-B66CAACEE30E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).